Gene-level copy-number profile of tumor specimen TCGA-BJ-A18Z-01A from TCGA case TCGA-BJ-A18Z, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 58.9 years (21,519 days).
Specimen TCGA-BJ-A18Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THCA.6d532180-0175-4610-8bfa-cca3a7c3697a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BJ-A18Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fb289e82-400c-4d56-8485-dd08d6bc0130

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,380; copy number 2: 57,428; copy number 3: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BJ-A18Z-01A-21D-A13V-01): tumor purity 0.33, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
